Surgical pathology report (de-identified scan), TCGA case TCGA-G2-AA3B, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-AA3B-01A (Primary Tumor).

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA, HIGH GRADE (GRADE 3), EXTENSIVELY INVASIVE INTO LAMINA PROPRIA AND MUSCULARIS MUCOSAE.

Muscularis propria present with no definitive evidence of tumor invasion into muscularis propria.

ICD-O.3
Carcinoma, urothelial NOS 8120/3
Site: Bladder NOS C67.9
J 5/11/14

GROSS DESCRIPTION

(A) BLADDER TUMOR - Received is a 6.3 x 5.0 x 1.8 cm aggregate of pink-tan, soft, rubbery tissue fragments. Entirely submitted in A1-A5.

CLINICAL HISTORY

Bladder cancer.

Source: NCI Genomic Data Commons file 5c668867-aa75-4ce4-a327-dd3034d374b7 (TCGA-G2-AA3B.F2410C77-1B33-47AA-A820-8A0E637234FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).